Gene-level copy-number profile of tumor specimen HCM-CSHL-0056-C18-01B from HCMI case HCM-CSHL-0056-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.1 years (27,431 days).
Specimen HCM-CSHL-0056-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd25db4c-a3e8-49fa-bc52-17372c4131fa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0056-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/803056d3-7c56-4c84-aa4b-4acf07f97f22

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 47; copy number 2: 3,441; copy number 3: 4,879; copy number 4: 47,719; copy number 5: 2,797; copy number 6: 12; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:25,247,345–25,249,279, 2 genes (within-gene range 0–3): SNORD115-42, SNORD115-43.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–4): AC009119.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 40. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
